Somatic mutation profile of tumor specimen TCGA-FE-A3PD-01A (aliquot TCGA-FE-A3PD-01A-11D-A21Z-08) from TCGA case TCGA-FE-A3PD, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 17.5 years (6,386 days).
Specimen TCGA-FE-A3PD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66bb89d9-1228-4167-8048-c212477b507b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FE-A3PD-10A (Blood Derived Normal), aliquot TCGA-FE-A3PD-10A-01D-A21Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14a677a0-b16b-4bf3-9c48-27bfb5d4e153

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, 5'Flank 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C7 | c.2218C>G p.L740V | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57480766; called by muse, mutect2, varscan2
- LAMA3 | c.6469G>A p.E2157K (on ENST00000313654 / NM_198129.4; = p.E548K on NM_000227.6) | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs766870171, COSV52535171, COSV52543199; called by muse, mutect2, varscan2
- OR6K2 | c.846G>C p.L282F | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.35); catalogued as COSV62744195; called by muse, mutect2, varscan2
- PLEKHG1 | c.2777G>C p.G926A | Missense Mutation (SNP) | VAF 147/388 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs760640018, COSV62051043; called by muse, mutect2, varscan2
- ROPN1B | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as COSV52543237; called by muse, mutect2, varscan2
- ZNF223 | c.350C>G p.S117C | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as COSV71572173; called by muse, mutect2, varscan2
- EEF1AKMT1 | c.240G>C p.V80= | Silent (SNP) | VAF 77/218 reads (35%) | catalogued as rs1321614130, COSV66965278; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498916 A>G | 5'Flank (SNP) | VAF 30/82 reads (37%) | catalogued as rs762026273; called by muse, mutect2, varscan2
